CCDI case PBCLZM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and unspecified parts of mouth.
https://portal.gdc.cancer.gov/cases/c0d0f127-da6b-4e9b-b54a-9472d6dd141e

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Mandible; Age at diagnosis: 4.3 years (1,578 days).

Biospecimens (3 samples)
- Sample 0DV147: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DV14K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV159: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
